CPTAC case C3N-00857 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e1d68cfb-04e7-43cb-b8c5-b523cf917636

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Dead; Days to death: 636 days (1.7 years); Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 64.5 years (23,545 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Residual disease: RX; Days to last known disease status: 636 days (1.7 years); Progression or recurrence: no; Days to last follow up: 636 days (1.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 14; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: No; Vascular invasion present: Yes.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 405 days (1.1 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 463 days (1.3 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 609 days (1.7 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 636 days (1.7 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 64 kg; Height: 172 cm; BMI: 21.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 90 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00857-21: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-00857-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 165 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00857-22: Section location: Larynx; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3N-00857-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 71 mg.
- Sample C3N-00857-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
